Somatic mutation profile of tumor specimen C3L-00369-02 (aliquot CPT0006470006) from CPTAC case C3L-00369, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-00369-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff7a04a8-faf3-46a7-b5db-2ec133ea31ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00369-31 (Blood Derived Normal), aliquot CPT0002660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de888b6d-afc9-4228-aae7-9a4372e9111d

The open-access MAF lists 141 somatic variants for this specimen: 95 protein-altering or splice-affecting, 25 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 25, Intron 13, Frame Shift Del 7, Frame Shift Ins 4, Splice Site 4, Nonsense Mutation 3, RNA 3, Splice Region 3, 3'UTR 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3246G>T p.R1082S | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1380107048; called by muse, mutect2, varscan2
- ADSS1 | c.197dup p.X66_splice | Splice Site (INS) | VAF 47/125 reads (38%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- ANGPTL1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.146); catalogued as COSV52367273; called by muse, mutect2, varscan2
- AOC1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs759480873, COSV62870757; called by muse, mutect2, varscan2
- CCT2 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780624649; called by muse, mutect2, varscan2
- CNGA3 | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 117/482 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.595); catalogued as CM014556; called by muse, mutect2, varscan2
- CUX2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs374906688; called by muse, mutect2, varscan2
- DNMT3A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 36/125 reads (29%) | catalogued as rs1449820788, COSV53051427; called by muse, mutect2, varscan2
- FAT4 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs745757322; called by muse, mutect2, varscan2
- FMNL3 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1420812239, COSV99526824; called by muse, mutect2, varscan2
- GP9 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 189/534 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as rs745846700, COSV100264665; called by muse, mutect2, varscan2
- GPR174 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99338376; called by muse, mutect2, varscan2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 75/458 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- KRT13 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs746117318, COSV55839059; called by muse, mutect2, varscan2
- LRRC53 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1026472696; called by muse, varscan2
- NCAM2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs201907310, COSV53103643; called by muse, mutect2, varscan2
- NEU4 | c.43C>T p.R15W (on ENST00000391969 / NM_001167602.3; = p.R27W on NM_080741.4) | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1430494348; called by muse, mutect2, varscan2
- POLQ | c.3697G>A p.V1233I | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1560097578; called by muse, mutect2, varscan2
- RAPGEF3 | c.1361G>A p.R454H (on ENST00000389212; = p.R412H on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs772695180, COSV99406568; called by muse, mutect2
- SIGLEC6 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as rs563918580, COSV58434842; called by muse, mutect2
- SMARCA4 | c.3466A>G p.T1156A | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100759360; called by muse, mutect2, varscan2
- SPTBN2 | c.6745G>A p.V2249I | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs774816936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM132C | c.2536G>A p.V846M | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs780371502; called by muse, mutect2, varscan2
- TTN | c.93650A>C p.K31217T (on ENST00000591111; = p.K23793T on NM_003319.4) | Missense Mutation (SNP) | VAF 80/233 reads (34%) | PolyPhen possibly damaging (0.801); catalogued as rs1322355821; called by muse, mutect2, varscan2
- VHL | c.512del p.K171Sfs*31 | Frame Shift Del (DEL) | VAF 162/328 reads (49%) | catalogued as COSV56544879; called by mutect2, pindel, varscan2
- YIPF5 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV50823145; called by muse, mutect2, varscan2
- ADAMTS20 | c.2273C>G p.P758R | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ADGRE5 | c.1912T>C p.Y638H (on ENST00000242786 / NM_078481.4; = p.Y545H on NM_001784.5) | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADH6 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AGBL4 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ALMS1 | c.1646A>C p.E549A | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ARHGAP30 | c.566A>C p.N189T | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP6V0A1 | c.2248+1G>A p.X750_splice (on ENST00000343619 / NM_001378531.1; = p.X744_splice on NM_005177.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- BCCIP | c.454_469del p.F152Vfs*13 | Frame Shift Del (DEL) | VAF 27/146 reads (18%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.3917_3918dup p.N1307* | Frame Shift Ins (INS) | VAF 70/251 reads (28%) | called by mutect2, pindel, varscan2
- BSPRY | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CARMIL2 | c.1824T>G p.N608K | Missense Mutation (SNP) | VAF 100/315 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CATSPERB | c.3258G>A p.W1086* | Nonsense Mutation (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- CCDC114 | c.156del p.L53Wfs*8 | Frame Shift Del (DEL) | VAF 68/241 reads (28%) | called by mutect2, pindel, varscan2
- CCDC141 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CEBPA | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 211/550 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP44 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- CHD9 | c.7657A>C p.N2553H (on ENST00000398510 / NM_001382353.1; = p.N2537H on NM_025134.7) | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLUL1 | c.1294T>G p.F432V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CNOT7 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CR2 | c.2830G>A p.G944R | Missense Mutation (SNP) | VAF 74/305 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DHRS4 | c.74C>G p.T25S | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMGDH | c.1620_1621dup p.N541Ifs*28 | Frame Shift Ins (INS) | VAF 48/146 reads (33%) | called by mutect2, varscan2
- DOCK9 | c.190A>C p.I64L (on ENST00000376460 / NM_001366676.2; = p.I65L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DOT1L | c.1045A>G p.S349G | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EBF3 | c.154del p.A52Rfs*80 | Frame Shift Del (DEL) | VAF 38/136 reads (28%) | called by mutect2, pindel, varscan2
- EFR3A | c.464A>C p.H155P | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- ELAC2 | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- EXPH5 | c.2688T>G p.D896E | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FHAD1 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GANC | c.1606dup p.E536Gfs*26 | Frame Shift Ins (INS) | VAF 49/160 reads (31%) | called by mutect2, pindel, varscan2
- GTF2I | c.1750+9_1750+10dup | Splice Region (INS) | VAF 17/156 reads (11%) | called by mutect2, pindel, varscan2
- HSDL1 | c.666+1G>A p.X222_splice | Splice Site (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- KCNK2 | c.794C>A p.T265K (on ENST00000444842 / NM_001017425.3; = p.T250K on NM_014217.4) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL7 | c.50A>T p.K17I | Missense Mutation (SNP) | VAF 106/436 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- LRRC37B | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MAML1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 157/482 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAPK1IP1L | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MTHFS | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 178/453 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NEK5 | c.1753T>A p.L585I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- NOM1 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- OR3A2 | c.772_774del p.C258del | In Frame Del (DEL) | VAF 63/209 reads (30%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1273_1282del p.K425Yfs*10 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel
- PITRM1 | c.2531_2532insCAC p.M844delinsIT | Splice Region (INS) | VAF 38/103 reads (37%) | called by mutect2, varscan2
- PITRM1 | c.2527_2529dup p.V843dup | In Frame Ins (INS) | VAF 32/109 reads (29%) | called by mutect2*, pindel, varscan2*
- PKHD1L1 | c.2368T>G p.Y790D | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, varscan2
- PLCD1 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 108/187 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RAB3GAP1 | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SAMD10 | c.365A>C p.D122A | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- SH2D4B | c.1261C>A p.Q421K (on ENST00000646907; = p.T346K on NM_207372.2) | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- SH3TC1 | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SKOR1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.039); called by muse, mutect2
- SLC25A3 | c.722C>T p.T241I (on ENST00000228318 / NM_005888.3; = p.T240I on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.34); called by muse, mutect2
- SMTNL2 | c.1221G>T p.Q407H (on ENST00000389313 / NM_001114974.2; = p.Q263H on NM_198501.3) | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SNAI1 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 80/177 reads (45%) | called by muse, mutect2, varscan2
- SPEN | c.4085_4088del p.R1362Ifs*46 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- TDRD10 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM131L | c.3494C>T p.S1165L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAP1 | c.491C>A p.T164K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TTLL7 | c.568T>A p.Y190N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP24 | c.2935A>G p.S979G | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- USP53 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- VASH1 | c.456-1G>A p.X152_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- WDR87 | c.129G>A p.Q43= | Splice Region (SNP) | VAF 63/183 reads (34%) | called by muse, mutect2, varscan2
- ZBED5 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.3347dup p.L1116Ffs*6 | Frame Shift Ins (INS) | VAF 45/159 reads (28%) | called by mutect2, pindel, varscan2
- ZFP28 | c.997T>A p.S333T | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF106 | c.408del p.D137Mfs*15 | Frame Shift Del (DEL) | VAF 44/229 reads (19%) | called by mutect2, pindel, varscan2
- ZNF497 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 39/385 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- ZNF677 | c.850A>T p.I284F | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARHGEF35 | c.898C>T p.L300= | Silent (SNP) | VAF 12/20 reads (60%) | called by mutect2, varscan2
- ATG13 | c.1218T>C p.D406= (on ENST00000359513 / NM_001346321.1; = p.D369= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 17/196 reads (9%) | called by muse, mutect2
- BTBD18 | c.495C>A p.T165= | Silent (SNP) | VAF 87/224 reads (39%) | called by muse, mutect2, varscan2
- C5orf15 | c.69C>T p.I23= | Silent (SNP) | VAF 136/375 reads (36%) | catalogued as rs747208047, COSV51548789; called by muse, mutect2, varscan2
- COL6A3 | c.9402C>T p.T3134= | Silent (SNP) | VAF 74/199 reads (37%) | called by muse, mutect2, varscan2
- CYGB | c.132C>T p.A44= | Silent (SNP) | VAF 35/211 reads (17%) | called by muse, mutect2, varscan2
- FREM3 | c.3930T>C p.T1310= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- HDAC6 | c.3468C>T p.Y1156= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- KLHL17 | c.1887G>T p.P629= | Silent (SNP) | VAF 99/229 reads (43%) | called by muse, mutect2, varscan2
- KXD1 | c.85C>T p.L29= | Silent (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- MROH2B | c.808A>C p.R270= | Silent (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- MYH13 | c.1755C>T p.A585= | Silent (SNP) | VAF 108/283 reads (38%) | catalogued as rs1040817237; called by muse, mutect2, varscan2
- NCKAP1L | c.2091C>G p.S697= | Silent (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- OBSCN | c.21501G>A p.R7167= | Silent (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- PCARE | c.2349T>A p.I783= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as COSV100527871; called by muse, mutect2, varscan2
- PKP3 | c.118C>A p.R40= | Silent (SNP) | VAF 111/279 reads (40%) | catalogued as rs1052027375; called by muse, mutect2, varscan2
- POP1 | c.1968G>A p.S656= | Silent (SNP) | VAF 87/405 reads (21%) | catalogued as rs1203972400, COSV100855814; called by muse, mutect2, varscan2
- RAB6A | c.411A>T p.S137= | Silent (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- REC8 | c.228T>G p.G76= | Silent (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- SAGE1 | c.747C>A p.I249= | Silent (SNP) | VAF 36/47 reads (77%) | called by muse, mutect2, varscan2
- SUFU | c.1440C>T p.D480= | Silent (SNP) | VAF 101/405 reads (25%) | called by muse, mutect2, varscan2
- UNC79 | c.4038C>G p.A1346= (on ENST00000393151 / NM_001346218.2; = p.A1169= on NM_020818.5) | Silent (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- VN1R5 | c.915G>A p.Q305= | Silent (SNP) | VAF 54/342 reads (16%) | called by muse, mutect2, varscan2
- ZNF324B | c.894G>C p.S298= | Silent (SNP) | VAF 10/258 reads (4%) | catalogued as COSV100351838, COSV60742768; called by muse, mutect2
- ZNF582 | c.762G>A p.P254= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs200288756; called by muse, mutect2, varscan2
- ABCA11P | n.942T>G | RNA (SNP) | VAF 140/387 reads (36%) | called by muse, mutect2, varscan2
- AK2 | c.*3917dup | 3'UTR (INS) | VAF 25/166 reads (15%) | called by mutect2, pindel, varscan2
- ALDH1L1 | c.858+35A>G | Intron (SNP) | VAF 145/406 reads (36%) | called by muse, mutect2, varscan2
- ANKRD11 | c.-59-7292G>T | Intron (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- CCDC38 | c.534-9G>T | Intron (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- FAM160A2 | c.2215+211G>T | Intron (SNP) | VAF 114/290 reads (39%) | called by muse, mutect2, varscan2
- HERC2P3 | n.877C>T | RNA (SNP) | VAF 31/706 reads (4%) | called by muse, mutect2
- LEO1 | c.1896+11dup | Intron (INS) | VAF 92/273 reads (34%) | called by mutect2, pindel, varscan2
- MEAK7 | c.153+453C>A | Intron (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- MIOX | c.341-11C>G | Intron (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- NPIPA7 | chr16:16374438 G>A | 5'Flank (SNP) | VAF 73/436 reads (17%) | catalogued as rs757063145; called by muse, mutect2, varscan2
- NPIPA7 | chr16:16374439 C>T | 5'Flank (SNP) | VAF 73/438 reads (17%) | catalogued as rs1370785882; called by muse, mutect2, varscan2
- PLCXD2 | c.*19A>T | 3'UTR (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- POLR3E | c.87+235G>T | Intron (SNP) | VAF 58/171 reads (34%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948675 T>C | 3'Flank (SNP) | VAF 110/449 reads (24%) | catalogued as rs1044877; called by muse, mutect2, varscan2
- RAB21 | c.220-37_220-33del | Intron (DEL) | VAF 40/127 reads (31%) | called by mutect2, pindel, varscan2
- TCF4 | c.305-168T>C | Intron (SNP) | VAF 56/191 reads (29%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.308-26C>G | Intron (SNP) | VAF 107/260 reads (41%) | called by muse, mutect2, varscan2
- TPM1 | c.564-34T>C | Intron (SNP) | VAF 116/332 reads (35%) | called by muse, mutect2, varscan2
- UGGT2 | c.3387+12T>A | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, varscan2
- XIST | n.8559T>A | RNA (SNP) | VAF 37/123 reads (30%) | called by muse, mutect2, varscan2
